Somatic mutation profile of tumor specimen TCGA-AX-A3GI-01A (aliquot TCGA-AX-A3GI-01A-11D-A20S-09) from TCGA case TCGA-AX-A3GI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.8 years (24,388 days).
Specimen TCGA-AX-A3GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2ff3f67-1abd-4482-b9f8-955c9c6cf3fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3GI-10A (Blood Derived Normal), aliquot TCGA-AX-A3GI-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de910d98-5cda-449e-8fba-59131f3a3219

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 36/74 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 41/43 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAD8 | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV99844389; called by muse, mutect2, varscan2
- ASCC3 | c.1274T>G p.I425S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100225865, COSV61229386; called by muse, mutect2
- ATXN2 | c.3805A>G p.M1269V (on ENST00000550104; = p.M1109V on NM_002973.4) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV100374314; called by muse, mutect2, varscan2
- BPIFB2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99401453; called by muse, mutect2, varscan2
- C1QTNF2 | c.217C>T p.R73W (on ENST00000393975; = p.R28W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as rs761209993, COSV67432482; called by muse, mutect2, varscan2
- CACNA1A | c.4888C>A p.R1630S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100802605, COSV64199885; called by muse, mutect2, varscan2
- CAPN9 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449609220, COSV99680548; called by muse, mutect2, varscan2
- CBLB | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913583; called by muse, mutect2, varscan2
- COL6A6 | c.5500G>A p.E1834K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as rs1246240959, COSV100650342; called by muse, mutect2, varscan2
- CPNE2 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as COSV99321443; called by muse, mutect2, varscan2
- DNAH7 | c.2058G>C p.K686N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.802); catalogued as COSV100415618; called by mutect2, varscan2
- DOK1 | c.520T>C p.Y174H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284098; called by muse, mutect2, varscan2
- FHOD3 | c.1581C>A p.S527R (on ENST00000359247 / NM_001281739.3; = p.S544R on NM_025135.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99941438; called by muse, mutect2
- H4C9 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV100574907; called by muse, mutect2, varscan2
- KCNH6 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100121105; called by muse, mutect2, varscan2
- LAMA2 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370535; called by muse, mutect2, varscan2
- LAMA4 | c.3794C>T p.T1265I (on ENST00000230538 / NM_001105206.3; = p.T1258I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038617; called by muse, mutect2, varscan2
- LPXN | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs373352618; called by muse, mutect2, varscan2
- MIA3 | c.1893A>C p.R631S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100719465; called by muse, mutect2, varscan2
- NBPF15 | c.645T>A p.H215Q | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); catalogued as COSV100977751; called by muse, mutect2, varscan2
- NOP14 | c.662T>G p.L221R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054708; called by muse, mutect2, varscan2
- OR4X1 | c.630C>G p.F210L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100186735, COSV60722430; called by muse, mutect2, varscan2
- PCDH9 | c.3290C>T p.A1097V (on ENST00000377865 / NM_203487.3; = p.A1063V on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as rs781165816, COSV100121354; called by muse, mutect2, varscan2
- PLXNB2 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100834102; called by muse, mutect2, varscan2
- PPP2R5A | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99806710; called by muse, mutect2, varscan2
- PRPF40B | c.1460G>A p.R487Q (on ENST00000380281; = p.R481Q on NM_012272.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs992806129, COSV99979895; called by muse, mutect2, varscan2
- RBM44 | c.249T>A p.D83E (on ENST00000611254; = p.D717E on NM_001080504.2) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.12); catalogued as COSV100389925; called by muse, mutect2, varscan2
- SENP3 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99547812; called by muse, mutect2, varscan2
- SLC49A3 | c.1013G>T p.G338V (on ENST00000404286 / NM_001294341.2; = p.G337V on NM_032219.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100448468; called by muse, varscan2
- STAT3 | c.1740G>C p.W580C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV99232835; called by muse, mutect2, varscan2
- TRIML2 | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100456114; called by muse, mutect2, varscan2
- USP53 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0.283); catalogued as rs537200720, COSV99917795; called by muse, mutect2, varscan2
- ARID2 | c.4318_4319del p.Q1440Afs*3 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by pindel, varscan2
- SHROOM3 | c.507_513del p.E170Nfs*6 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- TRAV40 | c.50C>A p.T17N | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF345 | c.344_382del p.E115_F127del | In Frame Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel
- ARHGAP25 | c.381C>T p.D127= (on ENST00000409202 / NM_001007231.3; = p.D120= on NM_014882.3) | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as COSV99771664; called by muse, mutect2, varscan2
- CLCN5 | c.2038C>A p.R680= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV100260220, COSV100260230; called by muse, mutect2
- LRRC4B | c.2133G>A p.T711= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100975945; called by muse, mutect2, varscan2
- NOTCH2 | c.4077C>T p.H1359= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1257579492, COSV99864536; called by muse, mutect2, varscan2
- RAPGEF2 | c.4455G>T p.G1485= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as COSV100031277; called by muse, mutect2, varscan2
- RUSC1 | c.2016C>T p.P672= (on ENST00000368352 / NM_001105203.2; = p.P203= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- SLC47A2 | c.1560T>C p.P520= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as rs754240711, COSV99449972; called by muse, mutect2, varscan2
- UGT2B4 | c.945C>T p.N315= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV100522464; called by muse, mutect2, varscan2
- SPAG8 | c.*230C>G | 3'UTR (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99428056; called by muse, mutect2, varscan2
